Somatic mutation profile of tumor specimen 5b5c81b1-4e73-48d3-9469-108edd (aliquot 5b5c81b1-4e73-48d3-9469-108edd_D6) from CPTAC case 02OV041, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV.
Specimen 5b5c81b1-4e73-48d3-9469-108edd: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e092866-d83b-4c6e-a3eb-dceaae20a4c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 2315af2e-1e3c-45ca-b4f0-ce2f23 (Blood Derived Normal), aliquot 2315af2e-1e3c-45ca-b4f0-ce2f23_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc39cbdc-998f-445b-af2f-d17c9d477961

The open-access MAF lists 137 somatic variants for this specimen: 98 protein-altering or splice-affecting, 20 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 20, Intron 8, Frame Shift Del 6, Splice Site 6, Nonsense Mutation 5, 5'UTR 4, RNA 3, 3'UTR 3, In Frame Del 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+2T>G p.X187_splice | Splice Site (SNP) | VAF 316/481 reads (66%) | hotspot (GDC flag); catalogued as CS114004, COSV52709511, COSV52900265, COSV53486980, COSV99478821; called by muse, mutect2, varscan2
- ANKRD36C | c.5303A>G p.H1768R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.234); catalogued as rs78902040; called by muse, mutect2, varscan2
- BAZ2B | c.6325A>G p.T2109A | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58603761; called by muse, mutect2, varscan2
- BRINP2 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 416/763 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64179765; called by muse, mutect2, varscan2
- CACNA2D3 | c.2248G>T p.D750Y | Missense Mutation (SNP) | VAF 129/306 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV55586080; called by muse, mutect2, varscan2
- CCDC88A | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as rs539601373; called by muse, mutect2, varscan2
- CD22 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.133); catalogued as rs1242090883; called by muse, mutect2, varscan2
- CD274 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs752493356, COSV67501177; called by muse, mutect2, varscan2
- FSCN2 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 115/135 reads (85%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as rs779493223; called by muse, mutect2, varscan2
- GAL3ST4 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 102/241 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs755486643, COSV52784786; called by muse, mutect2, varscan2
- GALNT16 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1389922956; called by muse, mutect2, varscan2
- GAS2L1 | c.566C>G p.P189R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV53330331; called by muse, mutect2
- IRX4 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 139/421 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV51471897; called by muse, mutect2, varscan2
- KANK4 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1223119136; called by muse, mutect2, varscan2
- MAGEB6B | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 157/448 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as rs769938120; called by muse, mutect2, varscan2
- OPRM1 | c.821A>G p.D274G | Missense Mutation (SNP) | VAF 166/247 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV57686256; called by muse, mutect2, varscan2
- PASD1 | c.2104C>A p.P702T | Missense Mutation (SNP) | VAF 254/599 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as COSV64855574; called by muse, mutect2, varscan2
- PC | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 65/318 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs757589132; called by muse, mutect2, varscan2
- PCDHA4 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 590/758 reads (78%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as rs1554125084, COSV63541767; called by muse, varscan2
- PTPRU | c.3926C>T p.S1309L | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777652634; called by muse, mutect2, varscan2
- RC3H2 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 173/597 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1260024004, COSV61800875; called by muse, mutect2, varscan2
- SEM1 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.583); catalogued as rs1215606937; called by muse, mutect2, varscan2
- SGK1 | c.148A>C p.K50Q | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs1425345145; called by muse, mutect2, varscan2
- TOMM70 | c.1126A>G p.M376V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs751540536; called by muse, mutect2, varscan2
- VIP | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772117174, COSV100923919; called by muse, mutect2, varscan2
- VIT | c.1061G>C p.R354P (on ENST00000389975 / NM_001177969.1; = p.R369P on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs773547450, COSV64895194; called by muse, mutect2, varscan2
- XKR4 | c.840C>G p.S280R | Missense Mutation (SNP) | VAF 148/374 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867273479; called by muse, mutect2, varscan2
- ACBD3 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ADAMTS3 | c.230del p.P77Lfs*19 | Frame Shift Del (DEL) | VAF 204/576 reads (35%) | called by mutect2, pindel, varscan2
- AGPAT3 | c.843+2T>C p.X281_splice | Splice Site (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- AKR1B15 | c.784A>T p.I262F | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ALPK3 | c.143+2T>G p.X48_splice | Splice Site (SNP) | VAF 67/94 reads (71%) | called by muse, mutect2, varscan2
- ANPEP | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ARMC3 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- C2CD3 | c.4357A>T p.K1453* | Nonsense Mutation (SNP) | VAF 182/1140 reads (16%) | called by muse, mutect2, varscan2
- CAPN12 | c.1288C>G p.L430V | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEACAM20 | c.176A>T p.Q59L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CYP4F22 | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 132/324 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DCAF12L2 | c.1154A>G p.E385G | Missense Mutation (SNP) | VAF 177/471 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- DIP2C | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EEF1B2 | c.589A>G p.K197E | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPB41L3 | c.2221A>G p.T741A | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- EPB41L4B | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ESPL1 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- FAM43A | c.1128G>C p.L376F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM76A | c.200C>G p.T67R | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.4803_4817del p.E1601_E1605del | In Frame Del (DEL) | VAF 146/702 reads (21%) | called by mutect2, pindel, varscan2
- HAPLN4 | c.1136G>C p.W379S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- HK2 | c.173C>G p.T58S | Missense Mutation (SNP) | VAF 136/328 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- IL20 | c.379-1G>C p.X127_splice | Splice Site (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2, varscan2
- INPP5J | c.2746C>T p.Q916* (on ENST00000331075 / NM_001284285.2; = p.Q548* on NM_001002837.2) | Nonsense Mutation (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2
- ITIH5 | c.875T>C p.L292S | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- KCP | c.3881T>G p.L1294R (on ENST00000620378; = p.L1418R on NM_001366122.1) | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KDM3B | c.3061A>G p.K1021E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF17 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 298/762 reads (39%) | called by muse, varscan2
- KMT2A | c.2284C>G p.L762V | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KMT2C | c.10804G>A p.G3602R | Missense Mutation (SNP) | VAF 148/217 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT6B | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 243/814 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- KRT6B | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 250/825 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- LRRK2 | c.812G>C p.C271S | Missense Mutation (SNP) | VAF 33/522 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAP3K19 | c.2115C>G p.H705Q | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- METTL18 | c.768del p.V257* | Frame Shift Del (DEL) | VAF 140/292 reads (48%) | called by mutect2, pindel, varscan2
- MYH14 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2
- NCSTN | c.1861G>T p.V621L | Missense Mutation (SNP) | VAF 205/724 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- NR4A2 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 37/548 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUDCD3 | c.817T>A p.W273R | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4D11 | c.281A>C p.Y94S | Missense Mutation (SNP) | VAF 100/263 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- P2RY4 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 28/439 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.456); called by muse, mutect2
- PCM1 | c.1472+6A>G | Splice Region (SNP) | VAF 59/176 reads (34%) | called by muse, mutect2, varscan2
- PCNX1 | c.1839T>A p.S613R | Missense Mutation (SNP) | VAF 162/404 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PEA15 | c.79del p.C27Afs*61 | Frame Shift Del (DEL) | VAF 39/284 reads (14%) | called by mutect2, pindel, varscan2
- PLA2G7 | c.790_810del p.R264_I270del | In Frame Del (DEL) | VAF 63/258 reads (24%) | called by mutect2, pindel, varscan2
- PLXNA3 | c.4986+1G>A p.X1662_splice | Splice Site (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.266T>A p.L89H | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRDM5 | c.842G>C p.R281T | Missense Mutation (SNP) | VAF 182/290 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PRLR | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 137/341 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- PTPN14 | c.2764A>G p.N922D | Missense Mutation (SNP) | VAF 106/287 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB11FIP1 | c.3266C>T p.T1089I | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHBDF2 | c.132G>C p.Q44H | Missense Mutation (SNP) | VAF 128/160 reads (80%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RNF133 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RRM2B | c.799A>T p.T267S | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RSPH10B2 | c.2572C>T p.P858S | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- SAMD9L | c.2247_2283del p.L750Sfs*6 | Frame Shift Del (DEL) | VAF 70/228 reads (31%) | called by mutect2, pindel, varscan2
- SCGB1D4 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SLCO2B1 | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SPHKAP | c.2388C>A p.D796E | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STIL | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TAF9B | c.602C>A p.T201K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TAFA3 | c.80_110del p.L27Pfs*12 | Frame Shift Del (DEL) | VAF 43/150 reads (29%) | called by mutect2, pindel, varscan2
- TMEM239 | c.565G>C p.D189H (on ENST00000361033 / NM_001318207.1; = p.D146H on NM_001167670.3) | Missense Mutation (SNP) | VAF 101/348 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSPYL6 | c.909C>G p.Y303* | Nonsense Mutation (SNP) | VAF 117/760 reads (15%) | called by muse, mutect2, varscan2
- TTC12 | c.577-2A>T p.X193_splice | Splice Site (SNP) | VAF 69/278 reads (25%) | called by muse, mutect2, varscan2
- WDR93 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- WNT6 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, varscan2
- YPEL1 | c.-5_18del | Translation Start Site (DEL) | VAF 50/172 reads (29%) | called by mutect2, varscan2
- ZBTB40 | c.3586del p.Q1196Sfs*9 | Frame Shift Del (DEL) | VAF 179/517 reads (35%) | called by mutect2, pindel, varscan2
- ZMYM1 | c.1746T>G p.N582K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF229 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 194/457 reads (42%) | called by muse, mutect2
- ACAP3 | c.534G>C p.L178= | Silent (SNP) | VAF 48/178 reads (27%) | called by muse, mutect2, varscan2
- AQP3 | c.129G>C p.V43= | Silent (SNP) | VAF 91/228 reads (40%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.2364G>C p.L788= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as COSV99432392; called by muse, varscan2
- ASIC1 | c.447C>G p.P149= | Silent (SNP) | VAF 57/230 reads (25%) | called by muse, mutect2, varscan2
- CORIN | c.2607C>T p.F869= | Silent (SNP) | VAF 133/340 reads (39%) | called by muse, mutect2, varscan2
- DLG1 | c.441T>C p.N147= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- DNAH5 | c.11841G>T p.V3947= | Silent (SNP) | VAF 79/295 reads (27%) | called by muse, mutect2, varscan2
- MAP2 | c.4467T>A p.P1489= | Silent (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- MUC5B | c.12753A>G p.T4251= | Silent (SNP) | VAF 240/378 reads (63%) | called by muse, mutect2, varscan2
- P3H3 | c.1320G>A p.L440= | Silent (SNP) | VAF 176/474 reads (37%) | catalogued as rs371610008; called by muse, mutect2, varscan2
- PDGFRA | c.2859G>C p.L953= | Silent (SNP) | VAF 236/578 reads (41%) | called by muse, mutect2, varscan2
- POLI | c.1497T>A p.T499= | Silent (SNP) | VAF 47/61 reads (77%) | called by muse, mutect2, varscan2
- PTPN21 | c.2076C>A p.G692= | Silent (SNP) | VAF 124/446 reads (28%) | called by muse, mutect2, varscan2
- SLC10A1 | c.258G>A p.K86= | Silent (SNP) | VAF 152/464 reads (33%) | catalogued as rs368178722; called by muse, mutect2, varscan2
- SYTL4 | c.192C>T p.A64= | Silent (SNP) | VAF 143/415 reads (34%) | called by muse, mutect2, varscan2
- TNKS2 | c.1677C>A p.G559= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- TRMT1L | c.981G>C p.V327= | Silent (SNP) | VAF 49/144 reads (34%) | called by muse, mutect2, varscan2
- TRPV6 | c.1431G>T p.L477= | Silent (SNP) | VAF 113/302 reads (37%) | called by muse, mutect2, varscan2
- TYR | c.588A>G p.R196= | Silent (SNP) | VAF 85/321 reads (26%) | called by muse, mutect2, varscan2
- WNK3 | c.4677G>C p.L1559= | Silent (SNP) | VAF 45/130 reads (35%) | called by muse, mutect2, varscan2
- C22orf34 | n.491G>T | RNA (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- CCDC25 | c.76+705C>T | Intron (SNP) | VAF 23/63 reads (37%) | catalogued as rs761888398; called by muse, mutect2, varscan2
- DNAH14 | c.7486-5811T>A | Intron (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- FRMD4B | c.417-5213G>T | Intron (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- NQO2 | c.-81C>A | 5'UTR (SNP) | VAF 42/123 reads (34%) | called by muse, mutect2, varscan2
- NSUN6 | c.*44G>T | 3'UTR (SNP) | VAF 19/87 reads (22%) | catalogued as rs772688335; called by muse, mutect2, varscan2
- PDIA3P1 | n.1521G>A | RNA (SNP) | VAF 200/563 reads (36%) | called by muse, mutect2, varscan2
- PLCH2 | c.2959+129G>A | Intron (SNP) | VAF 42/502 reads (8%) | catalogued as rs903699133; called by muse, mutect2
- POU2F3 | c.-35G>T | 5'UTR (SNP) | VAF 14/64 reads (22%) | catalogued as rs779382954; called by muse, mutect2, varscan2
- PSG11 | c.*3_*14del | 3'UTR (DEL) | VAF 91/191 reads (48%) | called by mutect2, pindel, varscan2
- RNF168 | c.*7G>T | 3'UTR (SNP) | VAF 78/405 reads (19%) | called by muse, mutect2, varscan2
- S100A1 | c.142-221dup | Intron (INS) | VAF 119/253 reads (47%) | called by mutect2, pindel, varscan2
- SCD | c.-136_-95del | 5'UTR (DEL) | VAF 37/71 reads (52%) | called by mutect2, pindel, varscan2
- SNORD114-3 | n.45A>C | RNA (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- TAOK2 | chr16:29991428 del CAGCCCCTGCGGCGGG | 3'Flank (DEL) | VAF 41/111 reads (37%) | called by mutect2, pindel, varscan2
- TOR1AIP2 | c.-146-12113G>C | Intron (SNP) | VAF 50/155 reads (32%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.-7C>G | 5'UTR (SNP) | VAF 175/407 reads (43%) | called by muse, mutect2, varscan2
- VMP1 | c.-26-22G>C | Intron (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2, varscan2
- VPS35L | c.1224+19C>T | Intron (SNP) | VAF 240/616 reads (39%) | called by muse, varscan2
